Somatic mutation profile of tumor specimen MMRF_2557_1_BM_CD138pos (aliquot MMRF_2557_1_BM_CD138pos_T1_KHS5U_K15178) from MMRF case MMRF_2557, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 83.5 years (30,508 days).
Specimen MMRF_2557_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8d9f851-eeb3-4278-985e-9f4353d37811.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2557_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2557_1_PB_Whole_C3_KHS5U_K15177; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a9968103-f31c-4d8d-bdea-6771107de6da

The open-access MAF lists 104 somatic variants for this specimen: 44 protein-altering or splice-affecting, 12 silent, 48 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, 3'UTR 24, Silent 12, Intron 9, 5'UTR 6, Nonsense Mutation 5, 5'Flank 3, 3'Flank 3, RNA 3, Frame Shift Ins 2, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 17/157 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs121918464, COSV61004751, COSV61004889; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FAM110D | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 58/128 reads (45%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.005); catalogued as rs867542614; called by muse, mutect2, varscan2
- H4C5 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 92/218 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.511); catalogued as rs200288965; called by muse, mutect2
- IGHA1 | c.914G>A p.W305* | Nonsense Mutation (SNP) | VAF 23/161 reads (14%) | catalogued as rs1399717019; called by muse, mutect2, varscan2
- IGHJ6 | c.32G>A p.G11D | Missense Mutation (SNP) | VAF 11/45 reads (24%) | PolyPhen benign (0.069); catalogued as rs368585758; called by muse, varscan2
- IGHV2-70 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 60/76 reads (79%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs370286145; called by muse, varscan2
- IP6K1 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 25/206 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.719); catalogued as rs757004314, COSV58662971; called by muse, mutect2, varscan2
- KRT83 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.077); catalogued as rs533080987; called by muse, mutect2, varscan2
- MLXIPL | c.202C>T p.Q68* | Nonsense Mutation (SNP) | VAF 23/92 reads (25%) | catalogued as rs1554603036; called by muse, mutect2, varscan2
- PIM1 | c.94G>C p.E32Q | Missense Mutation (SNP) | VAF 64/142 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.334); catalogued as COSV65165584; called by muse, mutect2
- PKD1L1 | c.5168C>T p.A1723V | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as rs145295983; called by muse, mutect2, varscan2
- PLXNA3 | c.1409C>A p.P470Q | Missense Mutation (SNP) | VAF 40/40 reads (100%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs782501504, COSV100859981; called by muse, mutect2, varscan2
- SEMA3G | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 34/189 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs372952470; called by muse, mutect2, varscan2
- SOX8 | c.81C>G p.D27E | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as rs1172057798; called by muse, mutect2, varscan2
- SPHKAP | c.1484C>T p.A495V | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); catalogued as rs372776095; called by muse, mutect2, varscan2
- SPINK5 | c.154C>T p.Q52* | Nonsense Mutation (SNP) | VAF 25/88 reads (28%) | catalogued as COSV56258180; called by muse, mutect2, varscan2
- TRHDE | c.1730G>T p.R577I | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as COSV53835051, COSV99668350; called by muse, mutect2, varscan2
- WDR31 | c.803G>A p.R268Q (on ENST00000374193 / NM_001006615.3; = p.R267Q on NM_145241.5) | Missense Mutation (SNP) | VAF 272/383 reads (71%) | SIFT tolerated (0.05); PolyPhen benign (0.074); catalogued as rs373131738, COSV59145656; called by muse, mutect2, varscan2
- ZNF442 | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 94/428 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.096); catalogued as rs748194603, COSV54420538; called by muse, mutect2, varscan2
- ZNF559 | c.212dup p.L71Ffs*22 | Frame Shift Ins (INS) | VAF 40/138 reads (29%) | catalogued as rs747265027; called by mutect2, varscan2
- ADGRF1 | c.631G>A p.G211R | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C1QL2 | c.745G>A p.V249M | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CCSER1 | c.1960A>G p.T654A | Missense Mutation (SNP) | VAF 121/273 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.034); called by muse, varscan2
- CPA1 | c.634A>T p.T212S | Missense Mutation (SNP) | VAF 110/379 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRB2 | c.1270T>C p.C424R | Missense Mutation (SNP) | VAF 54/376 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNM2 | c.786C>A p.H262Q | Missense Mutation (SNP) | VAF 38/188 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DSCAML1 | c.3889G>A p.A1297T (on ENST00000321322; = p.A1237T on NM_020693.4) | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- EIF2AK3 | c.1764-4_1764-2del p.X588_splice | Splice Site (DEL) | VAF 49/103 reads (48%) | called by mutect2, pindel, varscan2
- FSIP2 | c.11999T>C p.V4000A | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- GANAB | c.1647C>A p.F549L | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- HSF2BP | c.356A>G p.Y119C | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- IGHV2-70D | c.70A>C p.K24Q | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- INAVA | c.1106C>T p.S369F | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.27); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- ITGA2 | c.2903G>C p.G968A | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MDH1B | c.94T>G p.F32V | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MRE11 | c.1942G>T p.E648* (on ENST00000323929 / NM_005591.4; = p.E620* on NM_005590.4) | Nonsense Mutation (SNP) | VAF 8/70 reads (11%) | called by muse, mutect2, varscan2
- MTMR4 | c.2396T>C p.L799P | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIM1 | c.92A>T p.K31M | Missense Mutation (SNP) | VAF 62/140 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2
- SLC34A3 | c.79_85+18del p.X27_splice | Splice Site (DEL) | VAF 67/469 reads (14%) | called by mutect2, pindel
- SPECC1 | c.1703C>T p.A568V | Missense Mutation (SNP) | VAF 11/161 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.011); called by muse, mutect2
- TENT5C | c.912dup p.D305Rfs*21 | Frame Shift Ins (INS) | VAF 26/159 reads (16%) | called by mutect2, pindel, varscan2
- TTC9 | c.176A>C p.E59A | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT tolerated (0.53); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- XPO7 | c.389T>G p.F130C | Missense Mutation (SNP) | VAF 64/144 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ZNF407 | c.5671C>T p.Q1891* | Nonsense Mutation (SNP) | VAF 42/96 reads (44%) | called by muse, mutect2, varscan2
- ANXA1 | c.420T>C p.I140= | Silent (SNP) | VAF 73/209 reads (35%) | called by muse, mutect2, varscan2
- ASPG | c.792C>T p.V264= | Silent (SNP) | VAF 33/56 reads (59%) | called by muse, mutect2, varscan2
- CELSR1 | c.3909C>T p.D1303= | Silent (SNP) | VAF 107/197 reads (54%) | catalogued as rs752792922; called by muse, mutect2, varscan2
- GABRA1 | c.909C>T p.S303= | Silent (SNP) | VAF 34/170 reads (20%) | called by muse, mutect2, varscan2
- MAB21L2 | c.501G>A p.V167= | Silent (SNP) | VAF 29/170 reads (17%) | called by muse, mutect2, varscan2
- MAPK12 | c.612G>A p.T204= | Silent (SNP) | VAF 85/85 reads (100%) | catalogued as rs374214502, COSV53132209; called by muse, mutect2, varscan2
- PCDHA12 | c.1362G>A p.A454= | Silent (SNP) | VAF 28/135 reads (21%) | catalogued as COSV56481412; called by muse, mutect2, varscan2
- PHETA1 | c.264G>A p.A88= | Silent (SNP) | VAF 51/137 reads (37%) | catalogued as rs759043573, COSV64059131; called by muse, mutect2, varscan2
- RP1 | c.3819A>G p.T1273= | Silent (SNP) | VAF 109/230 reads (47%) | catalogued as rs749819124; called by muse, mutect2, varscan2
- SLC24A2 | c.321C>T p.G107= | Silent (SNP) | VAF 39/177 reads (22%) | catalogued as rs761386724; called by muse, mutect2, varscan2
- TIMD4 | c.750G>A p.L250= | Silent (SNP) | VAF 14/69 reads (20%) | called by muse, mutect2, varscan2
- TNRC6C | c.4749C>T p.F1583= | Silent (SNP) | VAF 16/200 reads (8%) | catalogued as rs1280281723, COSV100049421; called by muse, mutect2
- ADAM1A | n.2080T>C | RNA (SNP) | VAF 34/57 reads (60%) | called by muse, mutect2, varscan2
- BUB1B | c.*328C>A | 3'UTR (SNP) | VAF 10/34 reads (29%) | called by muse, mutect2, varscan2
- C16orf97 | n.133G>A | RNA (SNP) | VAF 6/58 reads (10%) | catalogued as rs867285541; called by muse, mutect2, varscan2
- C6orf201 | c.-127C>T | 5'UTR (SNP) | VAF 8/60 reads (13%) | called by muse, mutect2, varscan2
- CACTIN | c.*324C>T | 3'UTR (SNP) | VAF 45/192 reads (23%) | called by muse, mutect2, varscan2
- CATSPERD | c.-100T>C | 5'UTR (SNP) | VAF 5/21 reads (24%) | called by muse, mutect2
- COPS6 | c.*4G>C | 3'UTR (SNP) | VAF 218/331 reads (66%) | catalogued as rs1052151030; called by muse, mutect2, varscan2
- CPEB4 | c.-971A>G | 5'UTR (SNP) | VAF 9/92 reads (10%) | called by muse, mutect2
- CSMD3 | c.*1110T>C | 3'UTR (SNP) | VAF 25/47 reads (53%) | called by muse, mutect2, varscan2
- CSNK1G3 | chr5:123616265 C>A | 3'Flank (SNP) | VAF 18/90 reads (20%) | called by muse, mutect2, varscan2
- CXCL6 | c.*604T>G | 3'UTR (SNP) | VAF 40/84 reads (48%) | called by muse, mutect2
- DCLRE1B | c.*1144A>T | 3'UTR (SNP) | VAF 28/85 reads (33%) | called by muse, mutect2, varscan2
- DUSP6 | c.-420A>G | 5'UTR (SNP) | VAF 53/124 reads (43%) | called by muse, mutect2, varscan2
- EFR3A | c.*2185G>A | 3'UTR (SNP) | VAF 29/62 reads (47%) | called by muse, mutect2, varscan2
- FAM107A | c.327+165T>G | Intron (SNP) | VAF 39/67 reads (58%) | called by muse, mutect2, varscan2
- FOXG1 | chr14:28772621 T>C | 3'Flank (SNP) | VAF 32/53 reads (60%) | called by muse, mutect2
- GSK3B | c.*221G>A | 3'UTR (SNP) | VAF 11/81 reads (14%) | called by muse, mutect2, varscan2
- H1-5 | c.-12T>C | 5'UTR (SNP) | VAF 78/200 reads (39%) | called by muse, varscan2
- IGSF22 | c.*20G>A | 3'UTR (SNP) | VAF 31/87 reads (36%) | called by muse, mutect2, varscan2
- KCNIP2 | c.418+47G>A | Intron (SNP) | VAF 17/39 reads (44%) | called by muse, mutect2, varscan2
- KCTD8 | c.*799A>G | 3'UTR (SNP) | VAF 18/107 reads (17%) | called by muse, mutect2, varscan2
- KIAA0895 | c.*2185A>T | 3'UTR (SNP) | VAF 7/60 reads (12%) | called by muse, mutect2, varscan2
- LINC01550 | chr14:97978105 C>A | 5'Flank (SNP) | VAF 12/18 reads (67%) | catalogued as rs1284352486; called by muse, mutect2, varscan2
- LMTK3 | chr19:48513169 C>T | 5'Flank (SNP) | VAF 76/321 reads (24%) | called by muse, mutect2, varscan2
- MAP2K5 | c.-539C>G | 5'UTR (SNP) | VAF 5/76 reads (7%) | called by muse, mutect2
- MGAM | c.*334C>G | 3'UTR (SNP) | VAF 15/65 reads (23%) | called by muse, mutect2, varscan2
- MIR4458 | chr5:8460770 del G | 5'Flank (DEL) | VAF 3/25 reads (12%) | called by mutect2, pindel
- MZF1 | c.581-94C>T | Intron (SNP) | VAF 15/91 reads (16%) | called by muse, mutect2, varscan2
- NDUFB10 | chr16:1965440 C>T | 3'Flank (SNP) | VAF 45/92 reads (49%) | called by muse, mutect2, varscan2
- OR9Q1 | c.*94G>T | 3'UTR (SNP) | VAF 132/193 reads (68%) | called by muse, mutect2, varscan2
- PCOLCE2 | c.*65T>C | 3'UTR (SNP) | VAF 26/230 reads (11%) | called by muse, mutect2, varscan2
- PRKAA2 | c.*3388T>C | 3'UTR (SNP) | VAF 31/61 reads (51%) | called by muse, mutect2, varscan2
- RAB2B | c.118+32A>G | Intron (SNP) | VAF 49/100 reads (49%) | catalogued as rs778612591; called by muse, mutect2, varscan2
- RAB2B | c.118+31G>T | Intron (SNP) | VAF 50/103 reads (49%) | called by muse, mutect2, varscan2
- REV3L | c.7184+19G>T | Intron (SNP) | VAF 16/61 reads (26%) | called by muse, mutect2, varscan2
- RHPN2P1 | n.968A>T | RNA (SNP) | VAF 28/303 reads (9%) | called by muse, mutect2
- S1PR3 | c.-148+4198C>A | Intron (SNP) | VAF 59/212 reads (28%) | called by muse, mutect2, varscan2
- SERPINB7 | c.*660_*664del | 3'UTR (DEL) | VAF 18/36 reads (50%) | called by mutect2, pindel*, varscan2*
- SHMT2 | c.*204G>A | 3'UTR (SNP) | VAF 7/60 reads (12%) | called by muse, mutect2, varscan2
- SPRY3 | c.*3632C>T | 3'UTR (SNP) | VAF 170/345 reads (49%) | called by muse, mutect2, varscan2
- SSU72 | c.224+1268A>C | Intron (SNP) | VAF 3/10 reads (30%) | called by muse, mutect2
- ST6GAL1 | c.*961T>G | 3'UTR (SNP) | VAF 30/130 reads (23%) | called by muse, mutect2, varscan2
- STAC | c.*1572G>A | 3'UTR (SNP) | VAF 55/189 reads (29%) | called by muse, mutect2, varscan2
- STX2 | c.*1756A>T | 3'UTR (SNP) | VAF 82/133 reads (62%) | called by muse, mutect2, varscan2
- TMEM169 | c.*963G>A | 3'UTR (SNP) | VAF 7/12 reads (58%) | called by muse, mutect2
- TMEM250 | c.*1290G>T | 3'UTR (SNP) | VAF 38/224 reads (17%) | called by muse, mutect2, varscan2
- TUSC1 | c.*826C>G | 3'UTR (SNP) | VAF 20/79 reads (25%) | called by muse, mutect2, varscan2
- UBAC2 | c.31+452T>A | Intron (SNP) | VAF 80/169 reads (47%) | called by muse, mutect2, varscan2
